CCDI case PBCJCC — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/6cbe518e-271d-4cdf-9fac-4ec6bce14385

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Central neurocytoma: ICD-O-3 morphology code: 9506/1; Tissue or organ of origin: Ventricle, NOS; Age at diagnosis: 16.1 years (5,894 days).

Biospecimens (3 samples)
- Sample 0DT9MQ: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DT9N9: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DT9NM: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
